Somatic mutation profile of tumor specimen TCGA-FT-A61P-01A (aliquot TCGA-FT-A61P-01A-11D-A30E-08) from TCGA case TCGA-FT-A61P, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 76.9 years (28,082 days).
Specimen TCGA-FT-A61P-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1ff7eb0d-672d-4406-a067-abc11e26a571.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FT-A61P-10A (Blood Derived Normal), aliquot TCGA-FT-A61P-10A-01D-A30H-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fb0012bf-9a24-4fab-b63d-a09acc03f84c

The open-access MAF lists 177 somatic variants for this specimen: 128 protein-altering or splice-affecting, 47 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 111, Silent 47, Nonsense Mutation 9, Frame Shift Del 3, Splice Site 2, Frame Shift Ins 2, 5'UTR 1, Splice Region 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- F11 | c.976C>T p.R326C | Missense Mutation (SNP) | VAF 16/174 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs28934608, CM993146; ClinVar: likely pathogenic; called by muse, mutect2
- ABCG4 | c.832C>G p.Q278E | Missense Mutation (SNP) | VAF 54/185 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.185); catalogued as rs1484701613, COSV56643169; called by muse, mutect2, varscan2
- ADAM15 | c.109G>C p.E37Q | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.999); catalogued as COSV99664833; called by muse, mutect2, varscan2
- ADAM22 | c.199C>T p.H67Y | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0.026); catalogued as COSV99716233; called by muse, varscan2
- ADAR | c.348G>C p.R116S | Missense Mutation (SNP) | VAF 13/128 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as COSV52714177; called by muse, mutect2
- ADGRE2 | c.901A>G p.I301V | Missense Mutation (SNP) | VAF 28/140 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV59692897; called by muse, mutect2, varscan2
- ADGRG2 | c.2856C>G p.H952Q (on ENST00000379869 / NM_001079858.3; = p.H949Q on NM_005756.4) | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.734); catalogued as COSV61338554; called by muse, mutect2, varscan2
- ANKRD44 | c.279G>C p.L93F | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56553278; called by muse, mutect2, varscan2
- ARMC3 | c.2583G>C p.L861F | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated (0.72); PolyPhen benign (0.127); catalogued as COSV53059686; called by muse, mutect2, varscan2
- ATP5ME | c.106C>T p.R36W | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as rs1394334947, COSV55325467; called by muse, mutect2, varscan2
- CCDC110 | c.1691A>G p.N564S | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.382); catalogued as COSV56870398; called by muse, mutect2, varscan2
- CCDC191 | c.377C>T p.P126L | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as rs755162939, COSV55671533; called by muse, mutect2, varscan2
- CDH26 | c.1531G>C p.E511Q | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.061); catalogued as COSV54845613; called by muse, mutect2, varscan2
- CHORDC1 | c.664G>C p.D222H | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.76); catalogued as COSV57705800; called by muse, mutect2, varscan2
- CHPF | c.1917C>G p.F639L | Missense Mutation (SNP) | VAF 70/166 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV60534396; called by muse, mutect2, varscan2
- CHSY3 | c.787G>C p.D263H | Missense Mutation (SNP) | VAF 18/163 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59275947; called by muse, mutect2, varscan2
- CLDN7 | c.100T>G p.S34A | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT tolerated (0.59); PolyPhen benign (0.03); catalogued as COSV100598083; called by muse, mutect2
- CNOT1 | c.4300G>C p.E1434Q | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55315196; called by muse, mutect2, varscan2
- CREB3 | c.746C>T p.S249F | Missense Mutation (SNP) | VAF 19/266 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.116); catalogued as COSV59206610; called by muse, mutect2
- CREBBP | c.5890C>T p.R1964C | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.27); catalogued as rs1278592398, COSV52139436; called by muse, mutect2, varscan2
- CSMD3 | c.9172G>A p.D3058N (on ENST00000297405 / NM_001363185.1; = p.D2889N on NM_052900.3) | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.443); catalogued as rs759864023, COSV52105606, COSV52257196; called by muse, mutect2, varscan2
- CUBN | c.4222C>A p.P1408T | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64713407; called by muse, mutect2, varscan2
- CUL7 | c.1522G>T p.D508Y | Missense Mutation (SNP) | VAF 14/176 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as COSV54815331; called by muse, mutect2
- DACT1 | c.1497G>T p.E499D | Missense Mutation (SNP) | VAF 28/212 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.056); catalogued as rs145184753, COSV60021305, COSV60021753; called by muse, mutect2, varscan2
- DDAH1 | c.760G>T p.D254Y | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.099); catalogued as COSV52302703; called by muse, mutect2, varscan2
- EIF2B2 | c.353T>G p.L118R | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT tolerated (0.53); PolyPhen benign (0.158); catalogued as COSV56720149; called by muse, mutect2
- ELMO1 | c.79A>T p.K27* | Nonsense Mutation (SNP) | VAF 16/176 reads (9%) | catalogued as COSV100163818; called by muse, mutect2
- EP400 | c.4210A>G p.M1404V | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV57769430; called by muse, mutect2, varscan2
- ERCC2 | c.131C>T p.S44L | Missense Mutation (SNP) | VAF 36/128 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV55540161; called by muse, mutect2, varscan2
- ETNK1 | c.656A>G p.H219R | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56884900; called by muse, mutect2, varscan2
- EVA1B | c.14G>A p.R5Q | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs759982436, COSV54634005; called by muse, mutect2, varscan2
- EVX2 | c.723G>A p.M241I | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.559); catalogued as COSV57963012; called by muse, mutect2, varscan2
- F13B | c.98G>T p.G33V | Missense Mutation (SNP) | VAF 47/210 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66373340, COSV66374568; called by muse, mutect2, varscan2
- FAM102A | c.595C>T p.R199W (on ENST00000373095 / NM_001035254.3; = p.R57W on NM_203305.2) | Missense Mutation (SNP) | VAF 15/148 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.712); catalogued as rs770352857, COSV55947740; called by muse, mutect2, varscan2
- FLG | c.3765A>C p.E1255D | Missense Mutation (SNP) | VAF 40/516 reads (8%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV64240262; called by muse, mutect2
- GSK3B | c.176C>T p.T59I | Missense Mutation (SNP) | VAF 41/260 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.021); catalogued as COSV51773767; called by muse, mutect2, varscan2
- GTF3C2 | c.1933C>T p.R645C | Missense Mutation (SNP) | VAF 120/515 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs747775019, COSV53125982; called by muse, mutect2, varscan2
- HEPH | c.1442G>A p.S481N (on ENST00000343002; = p.S214N on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs781686208, COSV100294401, COSV57966447; called by muse, mutect2
- HERC2 | c.3051-1G>C p.X1017_splice | Splice Site (SNP) | VAF 6/54 reads (11%) | catalogued as COSV55318467; called by muse, mutect2, varscan2
- HOXA1 | c.398G>A p.G133E | Missense Mutation (SNP) | VAF 11/144 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56065827; called by muse, mutect2
- HOXB8 | c.91G>A p.D31N | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0.174); catalogued as COSV53310231; called by muse, mutect2, varscan2
- HVCN1 | c.66C>A p.S22R | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54371760; called by muse, mutect2, varscan2
- IKBKB | c.1836C>G p.L612= | Splice Region (SNP) | VAF 74/121 reads (61%) | catalogued as rs946523062, COSV60596975; called by muse, mutect2, varscan2
- IKZF2 | c.451C>T p.Q151* | Nonsense Mutation (SNP) | VAF 6/26 reads (23%) | catalogued as COSV59577026; called by muse, mutect2
- IRX6 | c.1013G>A p.R338K | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.71); PolyPhen benign (0.007); catalogued as rs375761966, COSV51859524; called by muse, mutect2, varscan2
- ITGA8 | c.1063A>G p.R355G | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.486); catalogued as COSV65227368; called by muse, mutect2, varscan2
- KCNT2 | c.1705C>T p.Q569* | Nonsense Mutation (SNP) | VAF 7/87 reads (8%) | catalogued as COSV99652447; called by muse, mutect2
- KIAA0753 | c.2161C>A p.P721T | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.189); catalogued as rs777384286, COSV100785537; called by muse, mutect2, varscan2
- KRT40 | c.718G>A p.D240N | Missense Mutation (SNP) | VAF 27/160 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.721); catalogued as rs1362856346, COSV66696260; called by muse, mutect2, varscan2
- KRTAP1-1 | c.472T>C p.Y158H | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as COSV60398141; called by muse, mutect2, varscan2
- LACC1 | c.163G>A p.D55N | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV57828960; called by muse, mutect2, varscan2
- LILRB1 | c.649A>C p.I217L (on ENST00000427581; = p.I181L on NM_006669.6) | Missense Mutation (SNP) | VAF 32/228 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61117224; called by muse, varscan2
- LYST | c.8254T>G p.L2752V | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.632); catalogued as COSV67706038; called by muse, mutect2, varscan2
- MAMDC4 | c.3346G>C p.G1116R (on ENST00000445819; = p.G1037R on NM_206920.3) | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.962); catalogued as COSV56375407; called by muse, mutect2, varscan2
- MAST4 | c.7684G>C p.G2562R (on ENST00000403625 / NM_001164664.2; = p.G2373R on NM_015183.3) | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.929); catalogued as COSV99843421; called by muse, mutect2
- MKRN3 | c.1229G>T p.C410F | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58808708; called by muse, mutect2, varscan2
- MST1R | c.220A>G p.I74V | Missense Mutation (SNP) | VAF 15/141 reads (11%) | SIFT tolerated (0.51); PolyPhen benign (0.09); catalogued as COSV56567650; called by muse, mutect2, varscan2
- MYBL2 | c.1336G>C p.V446L | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.978); catalogued as COSV53829076; called by muse, mutect2, varscan2
- MYCBPAP | c.1130C>G p.S377C | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV100087893; called by muse, mutect2
- MYCBPAP | c.1169C>G p.S390C | Missense Mutation (SNP) | VAF 31/107 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV60406738; called by muse, mutect2, varscan2
- MYH3 | c.1759G>A p.V587M | Missense Mutation (SNP) | VAF 17/174 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs765585804, COSV56862181; called by muse, mutect2, varscan2
- NAA15 | c.1528G>A p.E510K | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56719085; called by muse, mutect2, varscan2
- NAP1L1 | c.109C>T p.Q37* | Nonsense Mutation (SNP) | VAF 10/61 reads (16%) | catalogued as COSV99673728; called by muse, mutect2, varscan2
- NBPF15 | c.1994G>A p.G665E | Missense Mutation (SNP) | VAF 144/455 reads (32%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0); catalogued as rs1462346555, COSV68836772; called by muse, mutect2, varscan2
- NCOA6 | c.2854del p.Q952Kfs*82 | Frame Shift Del (DEL) | VAF 14/85 reads (16%) | catalogued as COSV62862828; called by mutect2, pindel, varscan2
- NDUFAF7 | c.100G>C p.E34Q | Missense Mutation (SNP) | VAF 16/158 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.052); catalogued as rs769179986, COSV50017285; called by muse, mutect2, varscan2
- NEU3 | c.647T>A p.I216N | Missense Mutation (SNP) | VAF 26/145 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.196); catalogued as COSV53636208; called by muse, mutect2, varscan2
- NFXL1 | c.2407A>C p.K803Q | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.894); catalogued as COSV101040110, COSV101040593; called by muse, mutect2, varscan2
- NLGN4Y | c.1033G>A p.D345N | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59295413; called by muse, mutect2, varscan2
- NPY2R | c.530C>T p.A177V | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); catalogued as rs144347274; called by muse, mutect2, varscan2
- OLFM3 | c.1274C>T p.S425F (on ENST00000338858 / NM_001288821.1; = p.S405F on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/228 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58797858; called by muse, mutect2, varscan2
- OR4S2 | c.108T>G p.I36M | Missense Mutation (SNP) | VAF 264/913 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.671); catalogued as COSV56746511; called by muse, mutect2, varscan2
- PGAM2 | c.539G>A p.R180Q | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.044); catalogued as rs375305359, COSV99803760; called by muse, mutect2, varscan2
- PLCH2 | c.2555C>T p.T852M | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758351092, COSV53941577; called by muse, mutect2, varscan2
- PLXNB3 | c.1219G>A p.G407R | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs376853068, COSV62796807; called by muse, mutect2, varscan2
- POLR2A | c.1043G>T p.G348V | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100495600; called by muse, mutect2
- PPP1R32 | c.200T>C p.L67P | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV58544685; called by muse, mutect2, varscan2
- PRKCB | c.831A>C p.L277F | Missense Mutation (SNP) | VAF 33/121 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.221); catalogued as COSV57774842; called by muse, mutect2, varscan2
- PSMD3 | c.1442C>T p.S481F | Missense Mutation (SNP) | VAF 34/301 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); catalogued as rs1288367345, COSV52857172, COSV52858957; called by muse, mutect2, varscan2
- R3HDM2 | c.1224G>T p.Q408H | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV100715010; called by muse, mutect2
- RASGRF2 | c.965T>C p.L322S | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV54127659; called by muse, mutect2, varscan2
- RBM6 | c.611A>C p.D204A | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.734); catalogued as COSV56481853; called by muse, mutect2, varscan2
- ROS1 | c.6355G>A p.G2119R | Missense Mutation (SNP) | VAF 16/132 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63853873; called by muse, mutect2, varscan2
- RPS12 | c.325G>T p.V109L | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.163); catalogued as COSV57767004; called by muse, mutect2, varscan2
- RSBN1L | c.386T>G p.L129R | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.775); catalogued as COSV58507673; called by muse, mutect2, varscan2
- RSC1A1 | c.70G>C p.G24R | Missense Mutation (SNP) | VAF 28/248 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV60779501; called by muse, mutect2, varscan2
- RUFY2 | c.415C>T p.R139* | Nonsense Mutation (SNP) | VAF 12/47 reads (26%) | catalogued as rs768777155, COSV100700084; called by muse, mutect2, varscan2
- RUFY3 | c.679G>C p.E227Q | Missense Mutation (SNP) | VAF 31/124 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV56912788; called by muse, mutect2, varscan2
- S100PBP | c.921-1G>T p.X307_splice | Splice Site (SNP) | VAF 13/73 reads (18%) | catalogued as COSV63140026; called by muse, mutect2, varscan2
- SAP30 | c.374G>A p.R125K | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.137); catalogued as rs1246792526, COSV56634707; called by muse, varscan2
- SCNM1 | c.658G>A p.D220N | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV54860178; called by muse, mutect2, varscan2
- SDHAF2 | c.439A>G p.K147E | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT tolerated (0.45); PolyPhen benign (0.112); catalogued as rs756162021, COSV57099001; called by muse, mutect2, varscan2
- SESN3 | c.919C>T p.H307Y | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT tolerated (0.48); PolyPhen benign (0.106); catalogued as COSV53584381; called by muse, mutect2
- SHANK3 | c.3472A>T p.S1158C | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.54); catalogued as COSV53185586; called by muse, mutect2, varscan2
- SLC12A6 | c.2065A>C p.S689R (on ENST00000354181 / NM_001365088.1; = p.S638R on NM_005135.2) | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV51625166; called by muse, mutect2, varscan2
- SLCO1C1 | c.509C>T p.S170L | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as COSV56871204, COSV56873874; called by muse, mutect2, varscan2
- SMG1 | c.2117A>G p.H706R | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV101245467; called by muse, mutect2
- SNRPA | c.342G>C p.K114N | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.979); catalogued as COSV54680841; called by muse, mutect2, varscan2
- SNW1 | c.352G>A p.D118N | Missense Mutation (SNP) | VAF 45/322 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.69); catalogued as COSV55053900; called by muse, mutect2, varscan2
- SYCE1 | c.364G>A p.E122K (on ENST00000343131 / NM_001143764.3; = p.E86K on NM_130784.3) | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.135); catalogued as COSV58216734; called by muse, mutect2
- TBC1D1 | c.1556G>A p.R519K | Missense Mutation (SNP) | VAF 8/103 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV54717139; called by muse, mutect2
- TBC1D2B | c.2242G>A p.D748N | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.984); catalogued as COSV56040553; called by muse, mutect2, varscan2
- TCP11L1 | c.448A>G p.T150A | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.109); catalogued as COSV57514806; called by muse, mutect2, varscan2
- TECPR2 | c.326C>G p.S109* | Nonsense Mutation (SNP) | VAF 12/59 reads (20%) | catalogued as rs1350071661, COSV100849895; called by muse, mutect2, varscan2
- TMED1 | c.397G>T p.E133* | Nonsense Mutation (SNP) | VAF 21/188 reads (11%) | catalogued as COSV99284065; called by muse, mutect2, varscan2
- TMEM67 | c.2819T>C p.L940P | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60038156; called by muse, mutect2
- TNFRSF10B | c.1219G>A p.E407K | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.561); catalogued as COSV52391716; called by muse, mutect2, varscan2
- TP53BP1 | c.350C>T p.T117I | Missense Mutation (SNP) | VAF 20/211 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.261); catalogued as COSV55499424, COSV55511772; called by muse, mutect2
- UBA7 | c.563C>T p.S188F | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as rs750496969, COSV61092014; called by muse, mutect2, varscan2
- UQCC1 | c.786G>T p.M262I | Missense Mutation (SNP) | VAF 26/151 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV62902311; called by muse, mutect2, varscan2
- USP31 | c.3148G>A p.E1050K | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.036); catalogued as COSV54851267; called by muse, mutect2, varscan2
- VPS39 | c.1276C>T p.Q426* (on ENST00000348544 / NM_001301138.2; = p.Q415* on NM_015289.5) | Nonsense Mutation (SNP) | VAF 12/54 reads (22%) | catalogued as COSV100529050; called by muse, mutect2, varscan2
- WDR19 | c.431G>A p.C144Y | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.487); catalogued as rs1343959332, COSV56463970; called by muse, mutect2, varscan2
- WDR47 | c.518C>T p.A173V | Missense Mutation (SNP) | VAF 39/280 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as COSV63057651; called by muse, mutect2, varscan2
- WDR47 | c.33G>T p.E11D | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV63057664; called by muse, mutect2
- XKR8 | c.916C>T p.H306Y | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT tolerated (0.5); PolyPhen benign (0.005); catalogued as COSV65834747; called by muse, mutect2, varscan2
- ZFYVE19 | c.658A>G p.M220V (on ENST00000355341 / NM_001077268.2; = p.M210V on NM_032850.5) | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.021); catalogued as COSV54539910; called by muse, mutect2, varscan2
- ZFYVE9 | c.1160T>G p.L387R | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.58); catalogued as COSV55092778; called by muse, mutect2, varscan2
- ZKSCAN1 | c.608C>T p.P203L | Missense Mutation (SNP) | VAF 25/145 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV60873648; called by muse, mutect2, varscan2
- ZNF565 | c.1161C>G p.S387R (on ENST00000355114; = p.S347R on NM_152477.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT tolerated (0.51); PolyPhen benign (0.046); catalogued as COSV58410716; called by muse, mutect2, varscan2
- ZNF687 | c.2408C>G p.S803C | Missense Mutation (SNP) | VAF 13/122 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55016655; called by muse, mutect2, varscan2
- ZNF791 | c.244G>C p.E82Q | Missense Mutation (SNP) | VAF 42/183 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.393); catalogued as COSV58480615; called by muse, mutect2, varscan2
- ZZZ3 | c.943G>A p.E315K | Missense Mutation (SNP) | VAF 13/136 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.572); catalogued as COSV66231058; called by muse, mutect2
- EIF2AK4 | c.1903_1909dup p.V637Gfs*12 | Frame Shift Ins (INS) | VAF 8/56 reads (14%) | called by mutect2, varscan2
- EP300 | c.4933dup p.R1645Pfs*28 | Frame Shift Ins (INS) | VAF 21/79 reads (27%) | called by mutect2, pindel, varscan2
- EPS8 | c.1604dup p.Y535* | Nonsense Mutation (INS) | VAF 12/96 reads (13%) | called by mutect2, pindel, varscan2
- KIF19 | c.2421_2449del p.S808Gfs*26 | Frame Shift Del (DEL) | VAF 10/64 reads (16%) | called by mutect2, pindel
- NCOA6 | c.944del p.P315Lfs*24 | Frame Shift Del (DEL) | VAF 23/100 reads (23%) | called by mutect2, pindel, varscan2
- A1CF | c.1438T>C p.L480= (on ENST00000373993 / NM_138932.2; = p.L472= on NM_014576.4) | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as COSV50961639, COSV50999321; called by muse, mutect2, varscan2
- ANKS6 | c.1467C>T p.D489= | Silent (SNP) | VAF 13/59 reads (22%) | catalogued as rs746505940, COSV62049945; called by muse, mutect2, varscan2
- ARMH4 | c.1287T>C p.D429= | Silent (SNP) | VAF 9/69 reads (13%) | catalogued as COSV50763336; called by muse, mutect2, varscan2
- ATXN1 | c.84G>A p.E28= | Silent (SNP) | VAF 8/132 reads (6%) | catalogued as COSV55213861; called by muse, mutect2
- C16orf82 | c.24C>A p.P8= | Silent (SNP) | VAF 18/76 reads (24%) | called by muse, mutect2, varscan2
- CDCP2 | c.318C>T p.C106= | Silent (SNP) | VAF 6/62 reads (10%) | catalogued as rs772654576, COSV61283390; called by mutect2, varscan2
- CEBPE | c.631C>A p.R211= | Silent (SNP) | VAF 35/117 reads (30%) | catalogued as rs1236429877, COSV52829414, COSV52829550; called by muse, mutect2, varscan2
- CELSR1 | c.7113T>C p.N2371= | Silent (SNP) | VAF 8/50 reads (16%) | catalogued as COSV53085270, COSV53087826; called by muse, mutect2, varscan2
- CNTN3 | c.1428T>G p.T476= | Silent (SNP) | VAF 9/71 reads (13%) | catalogued as COSV55165301, COSV55184374; called by muse, mutect2, varscan2
- DPP8 | c.9G>A p.K3= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as COSV55677665; called by muse, mutect2, varscan2
- EHD3 | c.1561C>T p.L521= | Silent (SNP) | VAF 19/172 reads (11%) | catalogued as COSV59030041; called by muse, mutect2, varscan2
- EN1 | c.339G>A p.P113= | Silent (SNP) | VAF 22/74 reads (30%) | catalogued as COSV54630741; called by muse, mutect2, varscan2
- ENKD1 | c.388C>T p.L130= | Silent (SNP) | VAF 38/241 reads (16%) | catalogued as COSV54666991; called by muse, mutect2, varscan2
- FBLN2 | c.2376C>T p.A792= | Silent (SNP) | VAF 17/112 reads (15%) | catalogued as rs921024305, COSV55483152; called by muse, mutect2, varscan2
- FCGBP | c.12246C>T p.I4082= | Silent (SNP) | VAF 28/74 reads (38%) | catalogued as rs1308650602; called by muse, mutect2, varscan2
- FOLH1 | c.1650A>G p.P550= | Silent (SNP) | VAF 6/49 reads (12%) | catalogued as COSV57048063; called by muse, mutect2, varscan2
- FREM2 | c.5100G>A p.V1700= | Silent (SNP) | VAF 15/91 reads (16%) | catalogued as COSV54834699; called by muse, mutect2, varscan2
- GABRA3 | c.540C>G p.L180= | Silent (SNP) | VAF 13/93 reads (14%) | catalogued as rs766332263, COSV100942496, COSV100942612; called by muse, mutect2
- GNAI3 | c.1029C>T p.I343= | Silent (SNP) | VAF 10/73 reads (14%) | catalogued as COSV63983575; called by muse, mutect2, varscan2
- GREB1 | c.591A>G p.A197= | Silent (SNP) | VAF 26/156 reads (17%) | catalogued as COSV52184720; called by muse, mutect2, varscan2
- ITPRIPL1 | c.325C>T p.L109= (on ENST00000439118 / NM_001008949.3; = p.L117= on NM_178495.6) | Silent (SNP) | VAF 17/119 reads (14%) | catalogued as rs373516509; called by muse, mutect2, varscan2
- LPAR6 | c.72C>T p.F24= | Silent (SNP) | VAF 8/55 reads (15%) | catalogued as COSV57303464; called by muse, mutect2, varscan2
- MUC4 | c.15348G>C p.L5116= (on ENST00000463781 / NM_018406.7; = p.L880= on NM_004532.6) | Silent (SNP) | VAF 17/176 reads (10%) | catalogued as COSV57776138; called by muse, mutect2, varscan2
- MYH14 | c.5409G>A p.G1803= | Silent (SNP) | VAF 11/79 reads (14%) | catalogued as COSV51814799; called by muse, mutect2, varscan2
- MYH7 | c.2433G>A p.L811= | Silent (SNP) | VAF 9/82 reads (11%) | catalogued as rs1234646629, COSV62518277; called by muse, mutect2, varscan2
- NRDC | c.1899G>A p.V633= | Silent (SNP) | VAF 12/66 reads (18%) | catalogued as COSV61403613; called by muse, mutect2, varscan2
- OR51G2 | c.159C>A p.I53= | Silent (SNP) | VAF 29/89 reads (33%) | catalogued as COSV58992516; called by muse, mutect2, varscan2
- OR5J2 | c.595C>T p.L199= | Silent (SNP) | VAF 236/325 reads (73%) | catalogued as COSV56620763, COSV56622138; called by mutect2, varscan2
- P3H4 | c.573C>T p.V191= | Silent (SNP) | VAF 41/443 reads (9%) | catalogued as COSV58636139; called by muse, mutect2
- PARP10 | c.2700C>T p.H900= | Silent (SNP) | VAF 3/39 reads (8%) | catalogued as COSV100477849; called by muse, mutect2
- PCDHB10 | c.2022G>A p.P674= | Silent (SNP) | VAF 21/139 reads (15%) | catalogued as rs369381936; called by muse, mutect2, varscan2
- POU4F2 | c.1134C>T p.I378= | Silent (SNP) | VAF 18/131 reads (14%) | catalogued as rs572053159, COSV55583817, COSV99850480; called by muse, mutect2, varscan2
- PSMG2 | c.765T>C p.F255= | Silent (SNP) | VAF 20/130 reads (15%) | catalogued as COSV58288059; called by muse, mutect2, varscan2
- RPS6KA2 | c.1689G>A p.A563= | Silent (SNP) | VAF 8/67 reads (12%) | catalogued as rs774396701, COSV55819232, COSV99691929; called by muse, mutect2, varscan2
- SACS | c.11781G>A p.A3927= | Silent (SNP) | VAF 39/195 reads (20%) | catalogued as rs369998705, COSV66537269; ClinVar: likely benign; called by muse, mutect2, varscan2
- SGSM2 | c.2115A>T p.S705= (on ENST00000426855 / NM_001098509.2; = p.S750= on NM_014853.3) | Silent (SNP) | VAF 12/130 reads (9%) | catalogued as COSV52157322; called by muse, mutect2
- SLC37A3 | c.1224G>C p.A408= | Silent (SNP) | VAF 24/81 reads (30%) | catalogued as COSV58264273; called by muse, mutect2, varscan2
- SLC6A5 | c.2151C>T p.L717= | Silent (SNP) | VAF 45/148 reads (30%) | catalogued as rs150429051; called by muse, mutect2, varscan2
- STAG2 | c.1710C>G p.A570= | Silent (SNP) | VAF 13/43 reads (30%) | catalogued as COSV54355969; called by muse, mutect2, varscan2
- STON1 | c.85C>T p.L29= | Silent (SNP) | VAF 12/102 reads (12%) | catalogued as rs753896351, COSV59129089; called by muse, mutect2, varscan2
- TBR1 | c.417C>T p.I139= | Silent (SNP) | VAF 27/266 reads (10%) | catalogued as COSV67417670; called by muse, mutect2, varscan2
- TPBG | c.1113C>T p.L371= | Silent (SNP) | VAF 12/84 reads (14%) | catalogued as rs746758034, COSV63882494; called by muse, mutect2, varscan2
- TTN | c.13500A>G p.T4500= (on ENST00000591111; = p.T3573= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 13/68 reads (19%) | catalogued as rs370621465; ClinVar: likely benign; called by muse, mutect2, varscan2
- UNC45A | c.2454C>T p.D818= | Silent (SNP) | VAF 15/127 reads (12%) | catalogued as rs757271469, COSV67793590; called by muse, mutect2, varscan2
- UNC5A | c.1906C>T p.L636= | Silent (SNP) | VAF 13/58 reads (22%) | catalogued as rs1263603419, COSV52838882; called by muse, mutect2, varscan2
- UNC5C | c.2677C>T p.L893= | Silent (SNP) | VAF 8/98 reads (8%) | catalogued as COSV71659045; called by muse, mutect2
- ZNF517 | c.39G>A p.A13= | Silent (SNP) | VAF 13/111 reads (12%) | catalogued as rs769619930, COSV63464740; called by muse, mutect2, varscan2
- GSK3B | c.-1C>T | 5'UTR (SNP) | VAF 25/90 reads (28%) | catalogued as rs765195146, COSV99954405; called by muse, mutect2, varscan2
- SLC25A25 | c.262-9101C>T | Intron (SNP) | VAF 57/247 reads (23%) | catalogued as COSV66088253; called by muse, mutect2, varscan2
